Gene-level copy-number profile of tumor specimen TCGA-77-7465-01A from TCGA case TCGA-77-7465, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIA; Age at diagnosis: 59.0 years (21,548 days).
Specimen TCGA-77-7465-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.31812616-d89e-4878-a764-9942c623f411.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-77-7465-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 815 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/d332f06f-121a-412f-ace2-a6d7eaf4534c

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 23; copy number 1: 27,862; copy number 2: 27,860; copy number 3: 2,954; copy number 4: 964; copy number 5: 31; copy number 6: 15; copy number 8: 55; copy number 12: 44.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-77-7465-01A-11D-2041-01): tumor purity 0.68, ploidy 1.61, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 23 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:141,167,257–141,208,376, 2 genes: RNU6-904P, RPS16P3.
- chr9:37,915,898–38,069,227, 2 genes (within-gene range 0–1): SHB, RNU7-124P.
- chr14:102,777,449–103,241,972, 19 genes (within-gene range 0–1): TRAF3, RNU6-1316P, AMN, CDC42BPB, AL117209.1, RPL13P6, LBHD2, AL161669.1, EXOC3L4, AL161669.4, LINC00677, TNFAIP2, NDUFB4P11, RPL21P12, GCSHP2, LINC00605, AL161669.2, AL161669.3, RPL21P13.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 145 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:1,456,480–1,728,172, 11 genes, copy number 5 (within-gene range 2–5): LPCAT1, MIR6075, AC091849.2, SDHAP3, AC026412.3, AC091849.1, AC026412.1, AC026412.2, AC026412.4, MIR4277, AC112176.1.
- chr11:69,371,463–71,670,297, 64 genes, copy number 5–12 (within-gene range 5–18) (broad region; genes not listed).
- chr18:47,390–3,025,566, 70 genes, copy number 6–8 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 25,441. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
